Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A4G1, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A4G1-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name:	[REDACTED]	Accession #:	[REDACTED]
MRN:	[REDACTED]	Collected:	
DOB:	[REDACTED]	Received:	
Gender:	F	Location:	[REDACTED]
HCN:	[REDACTED]	Facility:	
Ordering MD:	[REDACTED]	Reported:	
Copy To:	[REDACTED]		

Specimen(s) Received

1. Parathyroid: Right Biopsy, Upper/QS
2. Thyroid: Total thyroid, stitch left upper pole

Diagnosis

1. No pathological diagnosis: Parathyroid (right upper) biopsy
2. Papillary carcinoma, encapsulated follicular variant with focal classical architecture, 1.7 cm, left lobe; and mild follicular nodular disease: Thyroid
- No pathological diagnosis: Lymph nodes, 2, isthmus
- No pathological diagnosis: Thymus, right and left perithyroidal
- Total thyroidectomy specimen.

Comment

The 1.7 cm nodule is an encapsulated follicular neoplasm that exhibits follicular growth as well as focal papillary (classical) architecture along with diagnostic nuclear features of papillary thyroid carcinoma. There is no evidence of capsular or vascular invasion. The features are those of a low risk papillary carcinoma.

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	2.9 cm
	2.2 cm
	1.0 cm
	Left lobe:
	3.7 cm
	2.1 cm
	1.5 cm
	Isthmus +/- pyramidal lobe:
	2.2 cm
	1.2 cm
	0.6 cm
Specimen Weight:	13.1 g
Tumor Focality:	Unifocal

ICD-O-3
carcinoma, papillary, follicular variant
site: thyroid, NOS c73.9
8340/3
lw
10/2/12

[page 2 of 3]
Surgical Pathology Consultation Report

----- DOMINANT TUMOR -----

Tumor Laterality: Left lobe
Tumor Size: Greatest dimension: 1.7cm
Additional dimension: 1.6 cm
Additional dimension: 1.4 cm
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, follicular variant $\geq 99\%$ per TSS
Classical (papillary) architecture
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Totally encapsulated
Tumor Capsular Invasion: Not identified
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: Not applicable
Primary Tumor (pT): pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of regional lymph nodes examined: 2
Number of regional lymph nodes involved: 0
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Adenomatoid nodule(s) or Nodular follicular disease
Parathyroid gland(s), within normal limits
Other: thymus with no pathological diagnosis

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Clinical History

Euthyroid, FNA (outside): Suspicious for Papillary Carcinoma

Gross Description

1. The specimen labelled with the patient's name and as "Parathyroid: Right biopsy, Upper QS" consists of a piece of tissue that measures 0.4 x 0.2 x 0.2 cm. It is frozen for intraoperative consultation.

1A frozen section block resubmitted

2. The specimen labeled with the patient's name and as "Thyroid: Total thyroid, stitch left upper pole" consists of a thyroid gland that is oriented with a stitch and weighs 13.1 g. The right lobe measures 2.9 cm SI x 2.2 cm ML x 1.0 cm AP, the left lobe measures 3.7 cm SI x 2.1 cm ML x 1.5 cm AP and the isthmus measures 2.2 cm SI x 1.2 cm ML x 0.6 cm AP. The external surfaces have fibrous adhesions and are painted with blue dye. No parathyroid glands and lymph nodes are identified grossly. The mid to lower left lobe contains a well delineated nodule that measures 1.6 cm SI x 1.7 cm ML x 1.4 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of left lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

2A-D right lobe, superior to inferior

2E-F isthmus

2G-N left lobe, superior to inferior

Quick Section Diagnosis

1. Parathyroid, right upper: Parathyroid tissue.

[page 3 of 3]
Surgical Pathology Consultation Report

Don't/Synchronous Primary noted		X

Source: NCI Genomic Data Commons file 4b0a265c-43d5-4298-bd47-81c5996b3cb3 (TCGA-EM-A4G1.EF0C5187-A9B3-4EFC-A2AE-A78381C4DD8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).